CCDI case PBBNEP — CCDI-MCI: Molecular Characterization Initiative (MCI)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026). Disease type: Soft Tissue Tumors and Sarcomas, NOS; Primary site: Other and ill-defined sites.
https://portal.gdc.cancer.gov/cases/16d3fb1b-afef-467f-b53d-e1c2fcc429f6

Demographics
Sex at birth: male; Race: american indian or alaska native.

Diagnoses (1)
1. Sarcoma, NOS: ICD-O-3 morphology code: 8800/3; Tissue or organ of origin: Other ill-defined sites; Age at diagnosis: 17.4 years (6,361 days).

Biospecimens (3 samples)
- Sample 0DD09J: Tissue type: Normal; Specimen type: Peripheral Whole Blood.
- Sample 0DD0A9: Tissue type: Tumor; Specimen type: Solid Tissue; Preservation method: Frozen.
- Sample 0DD0B0: Tissue type: Tumor; Specimen type: Solid Tissue.
